Surgical pathology report (de-identified scan), TCGA case TCGA-AA-A02H, project TCGA-COAD (Colon Adenocarcinoma), tissue source site Indivumed, specimen TCGA-AA-A02H-01A (Primary Tumor).

Internal Sample

Diagnosis:

This is a moderately to poorly differentiated adenocarcinoma of the colon (G2 to 3) with infiltration of all parietal layers and vascular infiltration (L1, V1) as well as six lymph node conglomerate metastases (6/12, N2)

and in II a gall bladder preparation with parts of an adenocarcinoma, possibly to be interpreted as a further spread of the colon cancer described.

in III parts of the liver with parts of the carcinoma described.

ICD-0-3

adenocarcinoma, NOS 8140/3

Site sigmoid colon C18.7 w 3/30/11

PIPA Discrepancy		☒
Pr of Malignancy History		☒
Qual/S. nchronous: Primary Malignancy	☒	☐
Reviewed: Initials	5/16/11	

Source: NCI Genomic Data Commons file 319dc9cd-8e8d-4e1c-9fee-44885a17dfc6 (TCGA-AA-A02H.3BEA7ED1-F6E7-4A2E-94B9-744503D3F0E7.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).